CCDI case PBBNKV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fe865e3d-8e9f-4332-a7a4-e3f03e5efb53

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,127 days).

Biospecimens (3 samples)
- Sample 0DDLPC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDLPI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDLPN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
